Gene-level copy-number profile of tumor specimen TCGA-13-0885-01A from TCGA case TCGA-13-0885, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.5 years (25,763 days).
Specimen TCGA-13-0885-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.20b9a875-71ea-4849-8942-a9dc2728836d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0885-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/71b9a030-b638-4f77-b19a-b028e98ee5ea

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 587; copy number 2: 8,630; copy number 3: 10,812; copy number 4: 12,172; copy number 5: 10,927; copy number 6: 6,333; copy number 7: 6,067; copy number 8: 2,903; copy number 9: 472; copy number 10: 700; copy number 11: 205.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0885-01A-02D-0399-01): tumor purity 0.49, ploidy 4.32, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,257 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:156,788,731–163,736,012, 99 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr8:114,282,067–140,458,579, 308 genes, copy number 9–10 (within-gene range 6–10) (broad region; genes not listed).
- chr10:1,957,589–19,816,278, 307 genes, copy number 9–11 (broad region; genes not listed).
- chr12:29,331,434–29,497,686, 5 genes, copy number 10: AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1.
- chr19:20,923,222–24,163,425, 148 genes, copy number 9 (broad region; genes not listed).
- chr20:10,672,695–10,994,924, 1 gene, copy number 10 (within-gene range 8–10): AL050403.2.
- chr20:10,875,333–32,608,893, 389 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 587. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
